Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6537, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6537-01A (Primary Tumor).

Department of Cancer Pathology

Examination: Histopathological examination

TCGA – D5 – 6537

Material: Partial organ resection – transverse colon

Physician in charge:

Material collected on: Material received on

Expected time of examination

Clinical diagnosis: transverse colon with tumour.

Examination performed on:

Macroscopic description:

14 cm length of the large intestine with a piece of mesocolon sized 12 x 5 x 2 cm and a fragment of omentum sized 22 x 11 x 1 cm.

Calliflower-shaped tumour sized 3 x 3.5 cm in the intestinal mucosa. The lesion surrounds 100% of the circumference, located 3 cm from the one cut line, and 3 cm from the opposite one. Minimal side margin is 1.8 cm. A polyp 0.5 cm diameter found off the tumour.

Microscopic description:

Adenocarcinoma tubulare partim mucinosum (G3). Infiltratio carcinomatosa tunicae muscularis propriae et telae adiposae pericolicae. Excision lines free of neoplastic lesions. Outside the tumour: Adenoma tubulare cum dysplasia gradus levioris. Omentum sine metastasibus. Metastases carcinomatosa in lymphonodo (No I/XI).

Histopathological diagnosis:

Adenocarcinoma tubulare mucinosum partim coli. Metastases carcinomatosa in lymphonodo (No I/XII). Tubular and partially mucinous adenocarcinoma of the colon. (G3, Duke C, Astler - Coller C2, pT3, pN1a).

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 092a188c-c3d2-4ec1-a22e-ffde60a8ec35 (TCGA-D5-6537.F05F81CD-FC57-4BE5-A21D-F41E00449893.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).